Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5186, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5186-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with right renal mass scheduled for partial nephrectomy.

TCGA-BP-5186

Specimens Submitted:

1: Right renal, tumor, partial nephrectomy

2: Lymph node, paracaval, excision

DIAGNOSIS:

1. Right renal, tumor, partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 1.9 cm. ✓

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor ✓

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney ✓

Comment: The tumor cells are immunoreactive for CA-IX while the vasculature is immunoreactive for CD-31.

2. Lymph node, paracaval, excision:

Lymph Nodes:

Not involved ✓

Number of nodes examined: 1

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	IMM RECUT	
	CA-1X.	
	CD31	
	NEG CONT	

Gross Description:

1). The specimen is received in formalin and is labeled "Right renal tumor, stitch marks deep surgical margin". It consists of a 4 x 4 x 2 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a fairly circumscribed golden yellow, hemorrhagic tumor, measuring 1.9 x 1.7 x 1.6cm. The clearance from the resection margin is 0.2 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:
FSC - frozen section control
T - tumor
M - margin
RS - representative sections

2). The specimen is received in formalin, labeled "pericaval lymph nodes" and consists of a fragment of fibrofatty tissue measuring 2.5 x 2.5 x 0.3 cm. No definite lymph nodes are notified. The specimen is entirely submitted.

Summary of sections:
FFT-- fibrofatty tissue

Summary of Sections:

Part 1: Right renal, tumor, partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
1	M	1
2	RS	2
1	T	1

Part 2: Lymph node, paracaval, excision

Block	Sect. Site	PCs
1	FFT	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

[page 3 of 3]
-
- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL CARCINOMA. MARGIN MARKED BY STITCH IS BENIGN.
(VR)
PERMANENT DIAGNOSIS: SAME
-

Source: NCI Genomic Data Commons file 8d9695b5-fa64-43e1-a9df-a8808695c0b5 (TCGA-BP-5186.6E5E9368-8DF2-488E-8514-CB05A639A3FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).